Somatic mutation profile of tumor specimen TARGET-30-PAHYWC-01A (aliquot TARGET-30-PAHYWC-01A-01W) from TARGET case TARGET-30-PAHYWC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 1.9 years (704 days).
Specimen TARGET-30-PAHYWC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccdfce21-8942-45d2-9cf6-2bac501f6fcd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAHYWC-10A (Blood Derived Normal), aliquot TARGET-30-PAHYWC-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/710b9378-ed85-443f-b1e1-2318b6c0afd6

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.4152C>A p.F1384L | Missense Mutation (SNP) | VAF 158/367 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as COSV61256115, COSV61265150; called by muse, mutect2, varscan2
- CARD11 | c.3032G>A p.R1011K | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67797031; called by muse, mutect2, varscan2
- NPAS1 | c.1392A>T p.K464N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53408958; called by muse, mutect2, varscan2
- OR1A1 | c.600C>G p.Y200* | Nonsense Mutation (SNP) | VAF 374/911 reads (41%) | catalogued as COSV58403171, COSV58404636; called by muse, mutect2, varscan2
- ROS1 | c.6037C>G p.L2013V | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63851522; called by muse, mutect2, varscan2
- TG | c.1507C>A p.Q503K | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV55065907; called by muse, mutect2, varscan2
- ZNF700 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV54310965; called by muse, mutect2, varscan2
- TTLL13P | c.617del p.G206Afs*22 | Frame Shift Del (DEL) | VAF 26/138 reads (19%) | called by mutect2, pindel, varscan2
- KRTAP19-4 | c.138T>C p.Y46= | Silent (SNP) | VAF 124/297 reads (42%) | catalogued as rs199610377, COSV61858226; called by muse, mutect2, varscan2
- TBC1D17 | c.1170G>A p.E390= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV55577161; called by muse, varscan2
- CFAP57 | c.1929+139C>A | Intron (SNP) | VAF 77/205 reads (38%) | catalogued as rs762225804, COSV65263677; called by muse, mutect2, varscan2
